Gene-level copy-number profile of tumor specimen TCGA-HN-A2NL-01A from TCGA case TCGA-HN-A2NL, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.1 years (20,483 days).
Specimen TCGA-HN-A2NL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.a5327c43-f90e-42b7-b76e-13602f606844.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HN-A2NL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a965238a-b05a-408b-bc94-45094dc10857

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 26,719; copy number 2: 28,085; copy number 3: 4,692; copy number 4: 275.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HN-A2NL-01A-11D-A18N-01): tumor purity 0.88, ploidy 1.62, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:18,886,622–23,528,093, 37 genes (within-gene range 0–1): UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15, CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 4,726 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–25,887,206, 398 genes, copy number 3 (broad region; genes not listed).
- chr3:142,912,116–169,720,293, 372 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr3:188,562,238–192,917,856, 43 genes, copy number 3: LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC, OSTN, OSTN-AS1, UTS2B, CCDC50, AC073365.1, PYDC2, Y_RNA, AC026320.2, AC026320.1, AC026320.3, RN7SKP222, FGF12, FGF12-AS1, FGF12-AS2, FGF12-AS3, AC026671.1, RNU1-20P, MB21D2.
- chr3:193,241,128–198,222,513, 174 genes, copy number 3 (broad region; genes not listed).
- chr5:4,967,764–18,746,173, 243 genes, copy number 3 (broad region; genes not listed).
- chr6:36,243,203–40,715,363, 90 genes, copy number 3 (broad region; genes not listed).
- chr7:108,470,417–117,883,675, 122 genes, copy number 3 (broad region; genes not listed).
- chr8:150,584–4,994,972, 61 genes, copy number 3 (within-gene range 0–3) (broad region; genes not listed).
- chr8:4,496,392–4,635,654, 2 genes, copy number 3: AC010941.1, AC022068.1.
- chr8:5,072,645–20,551,405, 402 genes, copy number 3 (broad region; genes not listed).
- chr8:75,120,409–86,818,558, 172 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr11:77,659,996–77,821,017, 1 gene, copy number 3 (within-gene range 2–3): RSF1.
- chr11:77,717,712–79,989,630, 41 genes, copy number 3 (within-gene range 1–3): RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1.
- chr12:66,767–9,313,241, 334 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr12:115,957,905–116,277,693, 1 gene, copy number 3 (within-gene range 2–3): MED13L.
- chr12:116,082,570–133,214,832, 508 genes, copy number 3 (broad region; genes not listed).
- chr13:89,181,324–114,337,626, 368 genes, copy number 3 (broad region; genes not listed).
- chr17:57,744,495–83,095,122, 849 genes, copy number 3–4 (broad region; genes not listed).
- chr18:47,390–10,422,360, 213 genes, copy number 3 (broad region; genes not listed).
- chr18:12,432,897–35,497,979, 330 genes, copy number 3–4 (broad region; genes not listed).
- chr18:35,591,737–35,597,599, 2 genes, copy number 4: MIR3975, AC090220.1.

Autosomal genes at a single copy (total copy number 1): 26,717. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
